Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A01F, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A01F-01A (Primary Tumor).

TCGA #: Sample ID #:]

Diagnosis:

Resected colon (sigma) with tumor-free oral and aboral resection margins, with two small tubular adenomas and mild dysplasia (synonymous: mild intraepithelial neoplasia), with a small leiomyoma of the lamina muscularis mucosa, as well as an ulcerated, moderately differentiated adenocarcinoma with infiltration of the perimuscular fatty tissue and with two local lymph node metastases (G2, pT3, L1, V0, R0 pN1 2/30).

ICD-0-3

adenocarcinoma, NOS 8140/3

Site: Sigmoid colon C18.7 per 3/30/11

✓

KMI

Source: NCI Genomic Data Commons file 4d2db2a1-f908-4495-9f38-7f42ce9775ee (TCGA-AA-A01F.6D0B0431-B2C4-41BE-9270-654790FA3170.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).